Somatic mutation profile of tumor specimen ALCH-ABEF-TTP1-A (aliquot ALCH-ABEF-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABEF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,940 days).
Specimen ALCH-ABEF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2399a78-a067-453f-9954-eac187ca4427.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABEF-NB1-A (Blood Derived Normal), aliquot ALCH-ABEF-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dfabbad-92ac-4899-bc7c-d292cbebf6fc

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Intron 3, 5'UTR 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE3 | c.1566G>T p.L522F | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs781326971; called by muse, mutect2, varscan2
- ADGRE3 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553930762, COSV53729841; called by muse, mutect2, varscan2
- APC | c.4379C>T p.A1460V | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as CD092698; called by muse, mutect2
- C20orf194 | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs368705348; called by muse, mutect2
- CASK | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV59363413; called by muse, mutect2, varscan2
- DCAF4L1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1263606997; called by muse, mutect2, varscan2
- DHX38 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs963298654; called by muse, mutect2, varscan2
- HPS4 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 129/578 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs150403254, COSV61103584; called by muse, mutect2, varscan2
- KCNS2 | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637479; called by muse, mutect2, varscan2
- MARCHF4 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); catalogued as rs563978288; called by muse, mutect2, varscan2
- OR2AG2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs752701441; called by muse, mutect2
- PEG3 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs768343805, COSV55627174; called by muse, mutect2, varscan2
- TNFRSF25 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765955208; called by muse, mutect2, varscan2
- TNR | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs776579268, COSV54882472; called by muse, mutect2, varscan2
- TRDV1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs575717965, COSV101153525; called by muse, varscan2
- TRIOBP | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV60379602; called by muse, mutect2, varscan2
- ZNF638 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | catalogued as COSV52487755; called by muse, mutect2
- FGFBP1 | c.409dup p.R137Kfs*13 | Frame Shift Ins (INS) | VAF 35/278 reads (13%) | called by mutect2, pindel, varscan2
- GSTM1 | c.125A>C p.D42A | Missense Mutation (SNP) | VAF 71/435 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCRTR2 | c.983+1G>T p.X328_splice | Splice Site (SNP) | VAF 46/434 reads (11%) | called by muse, mutect2
- ICAM5 | c.2362C>G p.L788V | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.243); called by muse, mutect2
- IQUB | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IRX5 | c.606_607insA p.E203Rfs*20 | Frame Shift Ins (INS) | VAF 19/187 reads (10%) | called by mutect2, pindel, varscan2
- KMT2A | c.9845T>A p.V3282D | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- NLRP14 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 103/1049 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- NT5DC4 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- PLEKHM2 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PMPCB | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTN4R | c.763_764insCTC p.Y254_L255insP | In Frame Ins (INS) | VAF 49/515 reads (10%) | called by mutect2, pindel
- SETD2 | c.5947del p.E1983Kfs*23 | Frame Shift Del (DEL) | VAF 51/347 reads (15%) | called by mutect2, pindel, varscan2
- SPDYA | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WWC3 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ADGRA1 | c.585G>A p.P195= | Silent (SNP) | VAF 28/283 reads (10%) | catalogued as rs769660163; called by muse, mutect2, varscan2
- CDH6 | c.2214C>T p.Y738= | Silent (SNP) | VAF 64/742 reads (9%) | catalogued as rs778720220, COSV54064868; called by muse, mutect2
- FOXC2 | c.252C>T p.A84= | Silent (SNP) | VAF 90/1620 reads (6%) | catalogued as rs1266428946; called by muse, mutect2
- HDAC9 | c.1773G>A p.P591= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs767995866, COSV67773498; called by muse, mutect2, varscan2
- MYH11 | c.579G>A p.Q193= | Silent (SNP) | VAF 63/1006 reads (6%) | called by muse, mutect2
- PRKDC | c.4407G>A p.P1469= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs763108417, COSV58056195; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1587C>A p.R529= (on ENST00000352766; = p.R450= on NM_181334.5) | Silent (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- PTPRT | c.3768C>T p.T1256= | Silent (SNP) | VAF 46/464 reads (10%) | catalogued as rs373259743; called by muse, mutect2
- SLC4A1 | c.1815C>T p.I605= | Silent (SNP) | VAF 38/169 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.91902T>C p.F30634= (on ENST00000591111; = p.F23210= on NM_003319.4) | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV60135338; called by muse, mutect2, varscan2
- TTN | c.177C>T p.S59= | Silent (SNP) | VAF 120/522 reads (23%) | catalogued as rs191057824, COSV100630376; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CELF6 | c.-210_-195del | 5'UTR (DEL) | VAF 62/238 reads (26%) | called by mutect2, pindel, varscan2
- DNAJC19 | c.280+39G>A | Intron (SNP) | VAF 42/384 reads (11%) | called by muse, mutect2, varscan2
- MGAT4EP | n.1369T>A | RNA (SNP) | VAF 68/696 reads (10%) | called by muse, mutect2
- PTCH2 | c.-30_-24del | 5'UTR (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- RRBP1 | c.2184+41G>A | Intron (SNP) | VAF 53/391 reads (14%) | catalogued as rs371926756; called by muse, mutect2, varscan2
- TMEM135 | c.*2884C>G | 3'UTR (SNP) | VAF 64/784 reads (8%) | called by muse, mutect2
- TPK1 | c.185+15153G>A | Intron (SNP) | VAF 32/325 reads (10%) | called by muse, mutect2
